Somatic mutation profile of tumor specimen TCGA-BR-7703-01A (aliquot TCGA-BR-7703-01A-11D-2053-08) from TCGA case TCGA-BR-7703, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 81.3 years (29,711 days).
Specimen TCGA-BR-7703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8704bab-7905-4b41-9622-e997d5016a5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7703-10A (Blood Derived Normal), aliquot TCGA-BR-7703-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf826279-df7e-460e-bc11-2f37550fddb9

The open-access MAF lists 748 somatic variants for this specimen: 585 protein-altering or splice-affecting, 150 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 397, Silent 150, Frame Shift Del 109, Nonsense Mutation 31, Frame Shift Ins 26, In Frame Del 9, Splice Region 7, Intron 7, Splice Site 4, RNA 3, Translation Start Site 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1643del p.L548* | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs1554082091; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 42/115 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- SYNE1 | c.23995C>T p.R7999* (on ENST00000367255 / NM_182961.4; = p.R7928* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 29/138 reads (21%) | catalogued as rs570916267, COSV55022729; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBX3 | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | hotspot (GDC flag); catalogued as COSV57473101; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 32/156 reads (21%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA1 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as rs201642049; called by muse, mutect2
- ABCA5 | c.3953A>G p.Y1318C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV67017597; called by muse, mutect2, varscan2
- ABCA5 | c.2636T>C p.M879T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as COSV67017601; called by muse, mutect2, varscan2
- ABCB4 | c.940C>A p.L314M | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55937440; called by muse, mutect2
- ABCD2 | c.1469_1471del p.G490del | In Frame Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs758097606; called by mutect2, pindel, varscan2
- ABCG2 | c.473dup p.N158Kfs*5 | Frame Shift Ins (INS) | VAF 28/147 reads (19%) | catalogued as rs767454866; called by mutect2, varscan2
- ABHD15 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV56195871; called by muse, mutect2, varscan2
- ACACB | c.4192del p.L1398Sfs*26 | Frame Shift Del (DEL) | VAF 11/117 reads (9%) | catalogued as rs1565953344, COSV58128358; called by mutect2, pindel
- ACADS | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs781119134, COSV54369405; called by muse, mutect2, varscan2
- ACRV1 | c.236C>A p.T79N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.643); catalogued as COSV59755080; called by muse, mutect2, varscan2
- ACTL6A | c.1265A>C p.Q422P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52023365; called by muse, mutect2, varscan2
- ACTL7A | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs369812697; called by muse, mutect2, varscan2
- ACTN2 | c.2425G>A p.V809I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs551605384, COSV63976257; called by muse, mutect2, varscan2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 42/96 reads (44%) | catalogued as COSV57774850; called by muse, mutect2, varscan2
- ADAM8 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs779346703, COSV69864882; called by muse, mutect2, varscan2
- ADAMTS18 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs149189203; called by muse, mutect2, varscan2
- ADAMTS19 | c.2064T>A p.N688K | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); catalogued as COSV50761317; called by muse, mutect2, varscan2
- ADAMTS4 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV63488106; called by muse, mutect2
- ADARB2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.691); catalogued as rs1349437398, COSV67223462; called by muse, mutect2, varscan2
- ADGRA1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765247097, COSV66926142; called by muse, mutect2, varscan2
- ADGRG1 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs541949258, COSV65635990; called by muse, mutect2, varscan2
- ADNP2 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV51540238; called by muse, mutect2, varscan2
- ALDH2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as rs757893333, COSV55668609; called by muse, mutect2, varscan2
- ALDH3B2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs565722840, COSV62428716; called by muse, mutect2, varscan2
- ALKBH3 | c.459C>T p.H153= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as rs1268112542, COSV57024750; called by muse, mutect2, varscan2
- ALMS1 | c.5554C>A p.P1852T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV52509809, COSV52513583; called by muse, mutect2, varscan2
- AMER2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1179493016, COSV100766325, COSV63438481; called by muse, mutect2, varscan2
- AMMECR1L | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55760266; called by muse, mutect2, varscan2
- AMPD3 | c.1904G>T p.S635I (on ENST00000396553 / NM_001025389.2; = p.S644I on NM_000480.3) | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67331492; called by muse, mutect2, varscan2
- ANKRD30A | c.875C>A p.P292H (on ENST00000611781; = p.P236H on NM_052997.2) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs781775542, COSV64613884; called by muse, mutect2, varscan2
- ANKS6 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.164); catalogued as COSV62050912; called by muse, mutect2, varscan2
- APC | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as CM040977, COSV57355920; called by muse, mutect2, varscan2
- APC2 | c.3130G>A p.A1044T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52019834; called by muse, mutect2, varscan2
- ARFIP2 | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV54447532; called by muse, mutect2, varscan2
- ARHGAP24 | c.1054A>G p.K352E (on ENST00000395184 / NM_001025616.3; = p.K259E on NM_031305.3) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV51990620; called by muse, mutect2, varscan2
- ASB10 | c.287G>C p.R96T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV51997486; called by muse, mutect2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs747570359; called by mutect2, varscan2
- ASGR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as rs1174966305, COSV52649110; called by muse, mutect2, varscan2
- ASNSD1 | c.316T>C p.S106P | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV53624089; called by muse, mutect2, varscan2
- ASPN | c.1040T>C p.I347T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65016313; called by muse, mutect2, varscan2
- ATAD5 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs770341123, COSV58976078; called by muse, mutect2, varscan2
- ATAD5 | c.4467G>A p.W1489* | Nonsense Mutation (SNP) | VAF 55/179 reads (31%) | catalogued as COSV58976084; called by muse, mutect2, varscan2
- ATG2A | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753373151, COSV65967326; called by muse, mutect2, varscan2
- ATP6V1B2 | c.956G>C p.G319A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV52354131; called by muse, varscan2
- ATRN | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.26); catalogued as COSV53529823; called by muse, mutect2, varscan2
- ATRN | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs768522267, COSV53529831; called by muse, mutect2, varscan2
- ATXN2L | c.3004del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | catalogued as rs771612620; called by mutect2, pindel, varscan2
- BCHE | c.476A>C p.K159T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV52258582; called by muse, mutect2, varscan2
- BCKDHB | c.742+2T>C p.X248_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV57515021; called by muse, mutect2, varscan2
- BECN1 | c.962T>C p.M321T | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV59312239; called by muse, mutect2, varscan2
- BEST2 | c.949-1G>T p.X317_splice | Splice Site (SNP) | VAF 17/161 reads (11%) | catalogued as COSV50369048; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRCC3 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV57463034; called by muse, mutect2, varscan2
- BRWD1 | c.3671C>T p.A1224V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1408247256, COSV60898570; called by muse, mutect2
- C15orf40 | c.457dup p.T153Nfs*16 | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | catalogued as rs751372654; called by mutect2, varscan2
- C1QTNF9B | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs759351817, COSV65944269, COSV65944337; called by muse, mutect2
- C2CD6 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs776476421, COSV53796858; called by muse, mutect2, varscan2
- CALB2 | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56940306; called by muse, mutect2, varscan2
- CAMK4 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56675325; called by muse, mutect2, varscan2
- CAMSAP1 | c.2971G>A p.V991M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV56724325; called by muse, mutect2, varscan2
- CASR | c.1828A>G p.S610G (on ENST00000490131; = p.S687G on NM_000388.4) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV56138814; called by muse, mutect2
- CBFA2T3 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV51922943, COSV51929210; called by muse, mutect2, varscan2
- CBL | c.1007+2T>C p.X336_splice | Splice Site (SNP) | VAF 27/95 reads (28%) | catalogued as COSV50644172; called by muse, mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 36/143 reads (25%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CC2D2A | c.3257C>A p.P1086Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV67504319; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC66 | c.2038C>T p.Q680* (on ENST00000394672 / NM_001353147.1; = p.Q646* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV58305566; called by muse, mutect2, varscan2
- CCDC78 | c.1207A>G p.N403D | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV53496919; called by muse, mutect2, varscan2
- CCDC88B | c.1550G>A p.G517D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.36); catalogued as COSV57266840; called by muse, mutect2, varscan2
- CCDC88C | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs764238956, COSV66239240; called by muse, mutect2, varscan2
- CCM2 | c.1085G>A p.S362N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV51849395; called by muse, mutect2, varscan2
- CCN4 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs778202911, COSV51533217; called by muse, mutect2
- CCNH | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56925422; called by muse, mutect2, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 44/175 reads (25%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel, varscan2
- CDCP1 | c.571G>T p.G191* | Nonsense Mutation (SNP) | VAF 8/140 reads (6%) | catalogued as COSV56106406; called by muse, mutect2
- CDH23 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV54940875; called by muse, mutect2, varscan2
- CDR2 | c.1097A>C p.K366T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV51676659; called by muse, mutect2, varscan2
- CELF3 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs757437858, COSV51884474; called by muse, mutect2, varscan2
- CELF4 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281650287, COSV58454381; called by muse, mutect2, varscan2
- CELSR1 | c.8556G>A p.G2852= | Splice Region (SNP) | VAF 4/29 reads (14%) | catalogued as COSV53093496; called by muse, mutect2
- CEMIP | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.404); catalogued as rs760551866, COSV54990479; called by muse, mutect2, varscan2
- CEP112 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV101210492; called by muse, mutect2, varscan2
- CEP250 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256686850, COSV61171399; called by muse, mutect2, varscan2
- CEP350 | c.7408C>T p.R2470C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs778785732, COSV62604980; called by muse, mutect2
- CERS4 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.058); catalogued as rs764705410, COSV52168143; called by muse, mutect2, varscan2
- CHD4 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs1202748112, COSV58906618; called by muse, mutect2, varscan2
- CHPT1 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57533853; called by muse, mutect2, varscan2
- CHSY3 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357437935, COSV59280453; called by muse, mutect2, varscan2
- CLEC11A | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs575741408, COSV51574432; called by muse, mutect2
- CNTN3 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs1239937044, COSV55176099; called by muse, mutect2, varscan2
- CNTNAP2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); catalogued as COSV100665182, COSV62208741; called by muse, mutect2, varscan2
- CNTNAP2 | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); catalogued as rs369919189, COSV62155012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COG4 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs747410167, COSV60423589; called by muse, mutect2, varscan2
- COL15A1 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs770735842, COSV66646669; called by muse, mutect2, varscan2
- COMMD2 | c.421A>G p.R141G | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as COSV71946535; called by muse, mutect2, varscan2
- CORO1A | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV54631545; called by muse, mutect2, varscan2
- CPPED1 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV55498963; called by muse, mutect2, varscan2
- CPZ | c.436T>C p.C146R (on ENST00000360986 / NM_001014447.3; = p.C135R on NM_003652.3) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59923945; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs769538822; called by mutect2, varscan2
- CSMD2 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53927229; called by muse, mutect2
- CSTF2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV63376362; called by muse, mutect2, varscan2
- CTNND1 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62384485; called by muse, mutect2, varscan2
- CUX1 | c.3401G>A p.R1134Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs782309779, COSV52904638; called by muse, mutect2, varscan2
- CXXC4 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV67296572; called by muse, mutect2, varscan2
- CYP39A1 | c.354A>T p.K118N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV51496946; called by muse, mutect2, varscan2
- CYP4Z1 | c.274A>C p.S92R | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as COSV61965441; called by muse, mutect2
- CYP7B1 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as rs771797585, COSV59591745; called by muse, mutect2, varscan2
- DAB2 | c.1832T>C p.M611T | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV57916048; called by muse, mutect2, varscan2
- DACT1 | c.1158G>T p.Q386H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1447434942, COSV60021786; called by muse, mutect2, varscan2
- DCAF12L1 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs1382846374, COSV64421963, COSV64422100; called by muse, mutect2, varscan2
- DCD | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.381); catalogued as rs755072961, COSV53201900; called by muse, mutect2, varscan2
- DCSTAMP | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV52576623; called by muse, mutect2, varscan2
- DCTN1 | c.1047G>A p.K349= | Splice Region (SNP) | VAF 30/121 reads (25%) | catalogued as rs778117603, COSV62620838; called by muse, mutect2, varscan2
- DDX58 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65883720; called by muse, mutect2, varscan2
- DGKI | c.964A>T p.T322S | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.215); catalogued as COSV55958483; called by muse, mutect2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as COSV56634983; called by mutect2, pindel, varscan2
- DNAH17 | c.7173G>T p.Q2391H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV101101321; called by muse, mutect2, varscan2
- DNAH7 | c.4805G>A p.R1602H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758390184, COSV56758146; called by muse, mutect2, varscan2
- DNAJA4 | c.830C>T p.T277M (on ENST00000343789; = p.T306M on NM_018602.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); catalogued as rs765263538, COSV59425399; called by muse, mutect2, varscan2
- DOCK8 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV66634590; called by muse, mutect2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 37/121 reads (31%) | catalogued as rs35482889; called by mutect2, varscan2
- DPY19L4 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 64/276 reads (23%) | catalogued as COSV68963222; called by muse, mutect2, varscan2
- DRD4 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1564913381, COSV51562637; called by muse, mutect2
- E4F1 | c.2242C>T p.Q748* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV57039804; called by muse, mutect2, varscan2
- EHMT2 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs756538741, COSV64996691; called by muse, mutect2, varscan2
- EIF2AK4 | c.4598T>C p.I1533T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs559599794, COSV55470090; called by muse, mutect2, varscan2
- EIF4G2 | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60598019; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 29/92 reads (32%) | catalogued as rs766700925; called by mutect2, varscan2
- ELP2 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 13/255 reads (5%) | catalogued as rs917647407, COSV60852106; called by muse, mutect2
- EML1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as rs749465112, COSV51747708; called by muse, mutect2, varscan2
- ENKUR | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs775521379, COSV58633798; called by muse, mutect2, varscan2
- ENTHD1 | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57321967; called by muse, mutect2
- EOLA2 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV62207390; called by muse, mutect2, varscan2
- EOLA2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs372900564, COSV62207397; called by muse, mutect2, varscan2
- EPHA5 | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777838691, COSV56653935; called by muse, mutect2, varscan2
- ERBB4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs769311799, COSV53519461; called by muse, mutect2, varscan2
- ETFBKMT | c.683G>A p.S228N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV55672075; called by muse, mutect2
- FAM155A | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV65569663; called by muse, mutect2, varscan2
- FAM155B | c.494dup p.L166Sfs*5 | Frame Shift Ins (INS) | VAF 18/30 reads (60%) | catalogued as rs769524017; called by mutect2, varscan2
- FAM181A | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50889560; called by muse, mutect2, varscan2
- FAM47B | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1209259469, COSV61454876; called by muse, mutect2, varscan2
- FARS2 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs750702672, COSV51165804; called by muse, mutect2, varscan2
- FAT2 | c.11584G>A p.A3862T | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs747251482, COSV55823165; called by muse, mutect2, varscan2
- FAT2 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1236101718, COSV55823173; called by muse, mutect2, varscan2
- FAT3 | c.10114C>T p.P3372S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV53133531; called by muse, mutect2, varscan2
- FAT4 | c.8201A>G p.D2734G | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58693285; called by muse, mutect2, varscan2
- FCER1A | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63667662; called by muse, mutect2, varscan2
- FER1L6 | c.4018G>A p.G1340R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs759909451, COSV67551017; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FILIP1 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV52734055; called by muse, mutect2, varscan2
- FLNC | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554396410, COSV100367578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT2 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs778655319, COSV58144787; called by muse, mutect2, varscan2
- FLT3 | c.2392G>A p.G798R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54048660; called by muse, mutect2, varscan2
- FLT4 | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56113192; called by muse, mutect2, varscan2
- FLT4 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs186187161, COSV56113216; called by muse, mutect2, varscan2
- FRAS1 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.353); catalogued as COSV53623302, COSV99352653; called by muse, mutect2, varscan2
- FRMD1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs533290722, COSV51963059; called by muse, mutect2, varscan2
- FUT8 | c.746G>A p.R249H (on ENST00000360689 / NM_001371534.1; = p.R86H on NM_004480.4) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV61286975; called by muse, mutect2, varscan2
- GAB1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770936099, COSV53757990; called by muse, mutect2, varscan2
- GABBR1 | c.208del p.E70Sfs*36 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | catalogued as rs1231267820; called by mutect2, varscan2
- GABPA | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61396774; called by muse, mutect2, varscan2
- GARRE1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.431); catalogued as COSV55100987; called by muse, mutect2, varscan2
- GAS2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV53409085; called by muse, mutect2, varscan2
- GATA3 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs776412274, COSV60519702; called by muse, mutect2, varscan2
- GATA3 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.32); catalogued as COSV60520182, COSV60520365; called by muse, mutect2
- GATD1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as COSV60592785; called by muse, mutect2, varscan2
- GBF1 | c.1216C>T p.R406C (on ENST00000369983 / NM_001377137.1; = p.R405C on NM_004193.3) | Missense Mutation (SNP) | VAF 31/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201251402, COSV64144511; called by muse, mutect2
- GCN1 | c.4181G>A p.R1394H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773103914, COSV56110161; called by muse, mutect2, varscan2
- GFOD2 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs552557039, COSV52058616; called by muse, mutect2
- GGN | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.027); catalogued as COSV53057541; called by muse, mutect2, varscan2
- GIMAP7 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as rs145339506, COSV57959733; called by muse, mutect2, varscan2
- GIPC3 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.015); catalogued as rs769477337, COSV59259007; called by muse, mutect2, varscan2
- GLDN | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV59090986; called by muse, mutect2, varscan2
- GLUL | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV59382623; called by muse, mutect2, varscan2
- GORASP1 | c.70_72del p.E24del | In Frame Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs1238971110; called by mutect2, pindel, varscan2
- GPHN | c.1268C>T p.A423V (on ENST00000315266 / NM_001377519.1; = p.A456V on NM_020806.5) | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV59484746; called by muse, mutect2, varscan2
- GPR151 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as COSV57038773; called by muse, mutect2, varscan2
- GPR61 | c.817del p.Q273Rfs*40 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs1171793286; called by mutect2, pindel, varscan2
- GRAMD4 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100730284; called by muse, mutect2
- GRK6 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs780128630, COSV62683161; called by muse, mutect2, varscan2
- GRM4 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1430746534, COSV65210203; called by muse, mutect2
- GRM8 | c.1934C>A p.T645K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58840334; called by muse, mutect2, varscan2
- GUCY2D | c.1022A>C p.Q341P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.431); catalogued as COSV54697011; called by muse, mutect2, varscan2
- H1-5 | c.67_69del p.K23del | In Frame Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs1463409355; called by pindel, varscan2
- H4C3 | c.244_245del p.V82Hfs*? | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs747366650; called by mutect2, pindel, varscan2
- HAUS6 | c.1475del p.N492Mfs*50 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1360468258; called by mutect2, pindel
- HCLS1 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57523579; called by muse, mutect2, varscan2
- HDDC2 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV59532545, COSV59533406; called by muse, mutect2, varscan2
- HERC2 | c.10723G>A p.G3575S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as rs1384202758, COSV55331648; called by muse, mutect2, varscan2
- HERC2 | c.8399G>A p.R2800H | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs368463146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIP1 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373608095, COSV61187980; called by muse, mutect2, varscan2
- HIVEP2 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50021131; called by muse, mutect2, varscan2
- HLA-DMB | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66870843; called by muse, mutect2, varscan2
- HMGN2 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV63524387; called by muse, mutect2
- HNRNPC | c.538C>T p.R180W (on ENST00000420743; = p.R167W on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV60145898; called by muse, mutect2, varscan2
- HNRNPDL | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV55023003; called by muse, mutect2, varscan2
- HOATZ | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs779633934, COSV60441753; called by muse, mutect2, varscan2
- HOMER1 | c.716C>A p.A239E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.142); catalogued as COSV56527853; called by muse, mutect2, varscan2
- HOXC5 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170696873, COSV54537387; called by muse, mutect2, varscan2
- HOXD4 | c.20T>C p.M7T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1265532710, COSV100106596; called by muse, mutect2, varscan2
- HS3ST4 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV58820933; called by muse, mutect2, varscan2
- HSF5 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as COSV60417705; called by muse, mutect2, varscan2
- HSPA12A | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.066); catalogued as rs575047261, COSV65022514, COSV65022894; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 19/149 reads (13%) | catalogued as rs760021495; called by mutect2, varscan2
- IGHG2 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.884); catalogued as rs371694856; called by muse, mutect2, varscan2
- IGKV1D-33 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101134028; called by muse, mutect2, varscan2
- IGSF1 | c.3556C>A p.P1186T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV63838392; called by muse, mutect2
- IGSF9B | c.2500G>A p.V834M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs771150072, COSV58068494; called by muse, mutect2, varscan2
- IL21R | c.1549del p.R517Gfs*38 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs748992699; called by mutect2, pindel, varscan2
- ILDR1 | c.1152del p.P385Qfs*24 (on ENST00000344209 / NM_001199799.2; = p.P341Qfs*24 on NM_175924.4) | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs760136285; called by mutect2, pindel, varscan2
- IRGQ | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as rs1373117947, COSV60670496; called by muse, mutect2, varscan2
- IRX1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1429660571, COSV100116537, COSV57360506; called by muse, mutect2, varscan2
- ITPK1 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50896811; called by muse, mutect2, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 50/301 reads (17%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KAT6A | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55907981; called by muse, mutect2, varscan2
- KAT6A | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV55907995; called by muse, mutect2
- KCNG4 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.53); catalogued as rs753556242, COSV57584612; called by muse, mutect2, varscan2
- KCNH8 | c.2338G>T p.E780* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as COSV60455959, COSV60468557; called by muse, mutect2, varscan2
- KCNMA1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as COSV54260296; called by muse, mutect2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs753256170; called by mutect2, pindel, varscan2
- KCNS3 | c.258del p.K87Sfs*54 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | catalogued as COSV100410961; called by mutect2, pindel, varscan2
- KDM5B | c.2651C>T p.T884M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs781211319, COSV52509461; called by muse, mutect2, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | catalogued as rs1339576763; called by mutect2, pindel, varscan2
- KIAA0895 | c.765C>G p.F255L (on ENST00000297063 / NM_001100425.2; = p.F204L on NM_015314.3) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV51711805, COSV51714399; called by muse, mutect2, varscan2
- KIAA0895 | c.218C>G p.S73C (on ENST00000297063 / NM_001100425.2; = p.S22C on NM_015314.3) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV51711834; called by muse, mutect2, varscan2
- KIAA1328 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs1346288146, COSV54452034; called by muse, mutect2, varscan2
- KIF21B | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754732012, COSV59760556; called by muse, mutect2, varscan2
- KIF9 | c.2149C>T p.Q717* (on ENST00000265529 / NM_001377474.1; = p.Q652* on NM_022342.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV55520798; called by muse, mutect2, varscan2
- KIR2DL1 | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52411793, COSV52412865; called by muse, mutect2
- KLHL6 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.021); catalogued as rs749942087, COSV58067504; called by muse, mutect2, varscan2
- KNL1 | c.6043G>T p.G2015* (on ENST00000346991 / NM_170589.5; = p.G1989* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV61156796; called by muse, mutect2, varscan2
- KREMEN1 | c.1093A>G p.S365G (on ENST00000407188; = p.S367G on NM_032045.5) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as COSV59913464; called by muse, mutect2
- KRTAP5-8 | c.68del p.G23Dfs*192 | Frame Shift Del (DEL) | VAF 20/158 reads (13%) | catalogued as rs1228869512; called by mutect2, varscan2
- KRTDAP | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 54/172 reads (31%) | catalogued as rs780621881, COSV58865440; called by muse, mutect2, varscan2
- LAMA5 | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as COSV53363541; called by muse, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 71/261 reads (27%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LDOC1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782286173, COSV65159075; called by muse, mutect2, varscan2
- LHX5 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs751056869, COSV55663255; called by muse, mutect2, varscan2
- LHX8 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV53957818; called by muse, mutect2, varscan2
- LIG1 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV54393321; called by muse, mutect2, varscan2
- LIMS1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as rs1268490748, COSV100185408; called by muse, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 33/65 reads (51%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMX1A | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 45/150 reads (30%) | catalogued as rs1396081975, COSV54221798; called by muse, mutect2, varscan2
- LPP | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1180201019, COSV57098966; called by muse, mutect2, varscan2
- LRCH1 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 150/498 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV60849333; called by muse, mutect2, varscan2
- LRP1B | c.13101del p.H4368Tfs*4 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | catalogued as rs751694974; called by mutect2, pindel, varscan2
- LRP5 | c.3961G>A p.A1321T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.207); catalogued as rs1370315674, COSV53718308; called by muse, mutect2, varscan2
- LRRN3 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV57821362; called by muse, mutect2, varscan2
- LTBP2 | c.1756del p.V586* | Frame Shift Del (DEL) | VAF 35/171 reads (20%) | catalogued as rs776807257; called by mutect2, pindel, varscan2
- LTF | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV51609325; called by muse, mutect2, varscan2
- LTN1 | c.3197T>C p.V1066A | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs764800659, COSV63734201; called by muse, mutect2, varscan2
- MADD | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs369513528, COSV60625001; called by muse, mutect2
- MAGI2 | c.2288C>A p.T763N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV62674612; called by muse, mutect2, varscan2
- MAPKBP1 | c.1040C>T p.T347I (on ENST00000456763 / NM_001128608.2; = p.T341I on NM_014994.3) | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1322587753, COSV52963716; called by muse, mutect2, varscan2
- MAPKBP1 | c.2470C>T p.R824* (on ENST00000456763 / NM_001128608.2; = p.R818* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | catalogued as COSV52963729; called by muse, mutect2
- MAZ | c.39del p.F14Sfs*15 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs767720617; called by mutect2, varscan2
- MBD3 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99336832; called by muse, mutect2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM10 | c.1106G>A p.C369Y (on ENST00000484800 / NM_182751.3; = p.C368Y on NM_018518.5) | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66335199; called by muse, mutect2, varscan2
- MDC1 | c.4538G>A p.R1513Q | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as rs148973631; called by muse, mutect2, varscan2
- MEIOB | c.1107T>G p.F369L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV58054661; called by muse, mutect2
- MEPCE | c.434dup p.G146Rfs*7 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | catalogued as rs760012501; called by mutect2, varscan2
- METTL21C | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV57432972; called by muse, mutect2, varscan2
- MOXD1 | c.1192A>G p.R398G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV60945557; called by muse, mutect2, varscan2
- MPP7 | c.881A>T p.Q294L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV61734541; called by muse, mutect2, varscan2
- MSL2 | c.1290del p.D431Tfs*4 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs1559954442; called by mutect2, pindel, varscan2
- MTCH1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV65320932; called by muse, mutect2, varscan2
- MTIF2 | c.1974del p.K658Nfs*4 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as rs770359991; called by mutect2, varscan2
- MUC16 | c.20081C>T p.A6694V | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs766976047, COSV67476258; called by muse, mutect2, varscan2
- MUC6 | c.6709C>A p.P2237T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.026); catalogued as COSV70144453; called by muse, mutect2, varscan2
- MYBBP1A | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); catalogued as COSV54599447; called by muse, mutect2, varscan2
- MYH13 | c.3955C>A p.L1319I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV52833679; called by muse, mutect2
- MYH6 | c.5299A>G p.M1767V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59305059; called by muse, mutect2, varscan2
- MYH6 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs533942127, COSV62448343, COSV62452078; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH9 | c.4817C>T p.S1606L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.157); catalogued as rs145319741; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- MYH9 | c.3127C>T p.R1043* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV53388808; called by muse, mutect2, varscan2
- MYO16 | c.2429T>C p.L810P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51802688; called by muse, mutect2, varscan2
- MYO6 | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100889247; called by muse, mutect2, varscan2
- MYT1L | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs761734045, COSV67718695; called by muse, mutect2, varscan2
- N4BP2L2 | c.2536C>T p.Q846* (on ENST00000674422; = p.Q417* on NM_033111.4) | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as rs746708541, COSV62633630; called by muse, mutect2, varscan2
- NAA20 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs768850188, COSV58548752, COSV58549613; called by muse, mutect2, varscan2
- NAA40 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 33/121 reads (27%) | catalogued as rs1315681097, COSV58161374; called by muse, mutect2, varscan2
- NAGLU | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56795363; called by muse, mutect2, varscan2
- NAT2 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV54062351; called by muse, mutect2, varscan2
- NCK1 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV56638163; called by muse, mutect2
- NECTIN3 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV60552123; called by muse, mutect2, varscan2
- NEFM | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV55330703; called by muse, mutect2, varscan2
- NISCH | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs748520977, COSV61900909; called by muse, mutect2, varscan2
- NKTR | c.565A>G p.R189G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.82); catalogued as rs762351816, COSV51770588, COSV51773126; called by muse, mutect2, varscan2
- NME8 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1301137299, COSV52252099; called by muse, mutect2, varscan2
- NPAS4 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60649474; called by muse, mutect2, varscan2
- NPFFR2 | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58151312; called by muse, mutect2, varscan2
- NPM3 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774468944, COSV63382227; called by muse, mutect2, varscan2
- NPR1 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs145787747, COSV64117934; called by muse, mutect2, varscan2
- NTRK1 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs369367198; called by muse, mutect2, varscan2
- NUP210 | c.403del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs762804106; called by mutect2, pindel, varscan2
- NUP98 | c.3034C>T p.R1012C (on ENST00000359171 / NM_001365126.1; = p.R995C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.316); catalogued as rs144100440, COSV61436913; called by muse, mutect2, varscan2
- NXPE1 | c.644A>G p.H215R (on ENST00000424269; = p.H73R on NM_152315.5) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1206772474, COSV52629820; called by muse, mutect2, varscan2
- OBSL1 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as COSV54723190; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 9/101 reads (9%) | catalogued as CD000269; called by mutect2, pindel
- OR2J2 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65848145; called by muse, mutect2, varscan2
- OR2T11 | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV58185712; called by muse, mutect2
- OR4C11 | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56353979; called by muse, mutect2, varscan2
- OR4S2 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as COSV56747432; called by muse, mutect2, varscan2
- OR56A1 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1215247016, COSV57363058; called by muse, mutect2, varscan2
- OR5H6 | c.355del p.S119Pfs*3 (on ENST00000642105; = p.S103Pfs*3 on NM_001005479.2) | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | catalogued as rs747281928; called by mutect2, varscan2
- OR5K1 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV60304640; called by muse, mutect2, varscan2
- OR8D2 | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV62487991, COSV62488659; called by muse, mutect2, varscan2
- PADI3 | c.1931T>C p.V644A | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV64934780; called by muse, mutect2, varscan2
- PANK1 | c.1502T>C p.M501T (on ENST00000307534 / NM_148977.2; = p.M217T on NM_138316.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as rs1438240531, COSV56808931; called by muse, mutect2, varscan2
- PAPPA | c.4584G>A p.W1528* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV60286667; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDH1 | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 123/384 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs996382340, COSV54615915; called by muse, mutect2, varscan2
- PCDH10 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52088101; called by muse, mutect2, varscan2
- PCDH8 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV58810903, COSV58813578; called by muse, mutect2
- PCDHB16 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.023); catalogued as rs781862762; called by muse, mutect2
- PCDHGB7 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); catalogued as COSV53976596; called by muse, mutect2, varscan2
- PCK2 | c.343_345del p.S115del | In Frame Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs751483556; called by mutect2, pindel, varscan2
- PCNX2 | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs778818683, COSV50819964, COSV99265505; called by muse, mutect2, varscan2
- PDGFB | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.751); catalogued as COSV58648234; called by muse, mutect2, varscan2
- PDGFB | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1028545582, COSV58648264; called by muse, mutect2, varscan2
- PER1 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.11); catalogued as rs1245820386, COSV57920497; called by muse, varscan2
- PGGT1B | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV56974303; called by muse, mutect2
- PGR | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.697); catalogued as rs1324015244, COSV54804532; called by muse, mutect2, varscan2
- PHOX2A | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198361707, COSV53356853; called by muse, mutect2, varscan2
- PHTF1 | c.302_305del p.V101Gfs*11 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs1557955843; called by pindel, varscan2
- PHYHIPL | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.07); catalogued as rs776129253, COSV65848467; called by muse, mutect2, varscan2
- PKP2 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs143038626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB1 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV62057790; called by muse, mutect2, varscan2
- PLD1 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV60569965; called by muse, mutect2, varscan2
- PLD5 | c.1600C>T p.R534W (on ENST00000442594; = p.R472W on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs140318994; called by muse, mutect2, varscan2
- PML | c.2344C>T p.Q782* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV51448997; called by muse, mutect2, varscan2
- PNMA8B | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV66536963; called by muse, mutect2, varscan2
- PPFIA3 | c.343C>T p.L115= | Splice Region (SNP) | VAF 17/82 reads (21%) | catalogued as rs749089037, COSV61952829; called by muse, mutect2, varscan2
- PPP6R1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV69800050; called by muse, mutect2, varscan2
- PREX1 | c.4031C>T p.A1344V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs374959294; called by muse, mutect2, varscan2
- PRKAG2 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55232921; called by muse, mutect2, varscan2
- PRLHR | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as rs763541855, COSV53304303; called by muse, mutect2, varscan2
- PRPF4B | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61784600; called by muse, mutect2, varscan2
- PRX | c.3569T>C p.V1190A | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV52522236; called by muse, mutect2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 48/128 reads (38%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTCH1 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV59481248; called by muse, mutect2, varscan2
- PTGR1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53029643; called by muse, mutect2
- PTPRO | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs141750255, COSV55522998; called by muse, mutect2, varscan2
- RAD51AP2 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.301); catalogued as COSV67588459; called by muse, mutect2, varscan2
- RAI1 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.034); catalogued as COSV55394912; called by muse, mutect2, varscan2
- RBFOX1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60954857, COSV60986955; called by muse, mutect2, varscan2
- RBM4 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs368114061, COSV59518026; called by muse, mutect2, varscan2
- RELN | c.10357C>T p.R3453* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as rs139326865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELN | c.10039A>G p.S3347G | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1450247215, COSV59013231; called by muse, mutect2, varscan2
- RFNG | c.663-3del | Splice Region (DEL) | VAF 6/41 reads (15%) | catalogued as rs1197699009; called by mutect2, pindel, varscan2
- RGS6 | c.976A>G p.S326G | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59583902; called by muse, mutect2, varscan2
- RHBG | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV54806815; called by muse, mutect2, varscan2
- RHOT2 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs780282687, COSV53471943; called by muse, mutect2, varscan2
- RIMS2 | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1421709669, COSV51652319, COSV51695388; called by muse, mutect2, varscan2
- RNF112 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.435); catalogued as rs754863920, COSV71327074; called by muse, mutect2, varscan2
- RNF40 | c.1004T>A p.L335Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61215452; called by muse, mutect2, varscan2
- ROR2 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs754411436, COSV65218042; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA6 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424030; called by muse, mutect2
- RSPH6A | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as rs755304600, COSV55573331; called by muse, mutect2, varscan2
- RYK | c.1688G>A p.R563Q (on ENST00000620660 / NM_001005861.2; = p.R560Q on NM_002958.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748716502, COSV56061992; called by muse, mutect2, varscan2
- SAMSN1 | c.410-2A>G p.X137_splice | Splice Site (SNP) | VAF 22/91 reads (24%) | catalogued as COSV53473175; called by muse, mutect2, varscan2
- SARDH | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); catalogued as COSV53831858, COSV53834342; called by muse, mutect2, varscan2
- SATB1 | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs777236078, COSV58670709; called by muse, mutect2, varscan2
- SCARF2 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.102); catalogued as COSV56732923; called by muse, mutect2, varscan2
- SCNN1D | c.884C>T p.A295V (on ENST00000338555; = p.A459V on NM_001130413.4) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV57642507; called by muse, mutect2, varscan2
- SDK1 | c.4528C>T p.R1510W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765428605, COSV67376333; called by mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEC63 | c.1586del p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | catalogued as rs758487924; called by mutect2, varscan2
- SEMA4A | c.1204G>C p.V402L | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV61773188; called by muse, mutect2, varscan2
- SEMG2 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs772703748, COSV65647631; called by muse, mutect2, varscan2
- SERINC2 | c.783C>T p.D261= (on ENST00000373709 / NM_178865.5; = p.D265= on NM_018565.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 55/198 reads (28%) | catalogued as rs558799797, COSV65490899; called by muse, mutect2, varscan2
- SERPINB8 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54639999; called by muse, mutect2, varscan2
- SETBP1 | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV56327546; called by muse, mutect2, varscan2
- SEZ6L | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748996632, COSV50658670; called by muse, mutect2, varscan2
- SFXN3 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV56520384; called by muse, mutect2, varscan2
- SH2D2A | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63885016; called by muse, mutect2, varscan2
- SHISAL2A | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1358308729, COSV101284279, COSV68979896; called by muse, varscan2
- SHOC2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as COSV54622800; called by muse, mutect2, varscan2
- SIGLEC1 | c.3008T>A p.L1003H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV52466624; called by muse, mutect2
- SIGLEC10 | c.1985A>T p.Q662L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV59483554; called by muse, mutect2
- SIPA1L2 | c.4111G>A p.V1371M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.456); catalogued as rs367638550; called by muse, mutect2, varscan2
- SIRT2 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs201911244, COSV99979184; called by muse, mutect2, varscan2
- SKIV2L | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs147878364; called by muse, varscan2
- SLC13A2 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58996344; called by muse, mutect2, varscan2
- SLC25A13 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1367925406, COSV55709489; called by muse, mutect2, varscan2
- SLC39A2 | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53870076, COSV53870502; called by muse, mutect2, varscan2
- SLC39A3 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.13); catalogued as rs371925515; called by muse, mutect2, varscan2
- SLC41A1 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65650870; called by muse, mutect2, varscan2
- SLC6A15 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57022791; called by muse, mutect2, varscan2
- SLC9A4 | c.2295G>T p.E765D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV54835855; called by muse, mutect2, varscan2
- SLTM | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1437133201, COSV100998718, COSV65849477; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs766085867, COSV100391091; called by mutect2, pindel, varscan2
- SMPDL3B | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV65855056; called by muse, mutect2, varscan2
- SNAPC2 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV54492631; called by muse, mutect2, varscan2
- SNX14 | c.1045C>T p.R349C (on ENST00000314673 / NM_001350535.1; = p.R305C on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs778527399, COSV59013557, COSV59013786; called by muse, mutect2, varscan2
- SOAT2 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as rs566077392, COSV56860044; called by muse, mutect2, varscan2
- SORCS1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.021); catalogued as COSV53878933; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | catalogued as rs371303534; called by mutect2, varscan2
- SPECC1 | c.1721C>T p.T574M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs761861967, COSV54960999; called by muse, mutect2, varscan2
- SPRED1 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754706111, CD113508, CM097991, COSV54437183; called by muse, mutect2, varscan2
- SPTB | c.3659A>G p.N1220S | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.372); catalogued as COSV67632989; called by muse, mutect2, varscan2
- SRC | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV62439492, COSV62440296; called by muse, varscan2
- ST14 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53831716; called by muse, mutect2, varscan2
- ST8SIA4 | c.811A>G p.N271D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | PolyPhen benign (0.038); catalogued as COSV99185089; called by muse, mutect2, varscan2
- STARD13 | c.2906G>T p.R969L (on ENST00000336934 / NM_001243476.3; = p.R851L on NM_052851.3) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs146449066, COSV99715412; called by muse, mutect2, varscan2
- STAU2 | c.1003C>T p.P335S (on ENST00000524300 / NM_001164380.2; = p.P303S on NM_014393.2) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV63309191; called by muse, mutect2, varscan2
- SULF1 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV52685607; called by muse, mutect2
- SVEP1 | c.1956G>T p.W652C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV57040091; called by muse, mutect2, varscan2
- SYNE2 | c.3467T>C p.L1156P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59956416; called by muse, mutect2, varscan2
- SYNE2 | c.17524G>A p.E5842K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.7); catalogued as rs769564739, COSV59956424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.20492G>A p.R6831K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59956435; called by muse, mutect2, varscan2
- SYNE3 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs143391386, COSV62077866; called by muse, mutect2, varscan2
- TAOK3 | c.139A>G p.S47G | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62401879; called by muse, mutect2, varscan2
- TBC1D13 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); catalogued as rs1215278709, COSV56354821; called by muse, mutect2, varscan2
- TCF3 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs749950119, COSV53650267; called by muse, varscan2
- TCF7L2 | c.1258C>T p.R420W (on ENST00000355995 / NM_001367943.1; = p.R397W on NM_030756.5) | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53335898; called by muse, mutect2, varscan2
- TDRD10 | c.327del p.K110Rfs*6 | Frame Shift Del (DEL) | VAF 45/244 reads (18%) | catalogued as rs781235407, COSV100873048; called by mutect2, pindel, varscan2
- TEAD2 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.317); catalogued as rs779655419, COSV55562806; called by muse, mutect2, varscan2
- TENM2 | c.5984C>T p.S1995L (on ENST00000518659 / NM_001122679.2; = p.S1756L on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs749412027, COSV69123809; called by muse, mutect2, varscan2
- TESK2 | c.812_814del p.D271del | In Frame Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs1313464719; called by pindel, varscan2
- TESMIN | c.1238T>C p.M413T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV54833556; called by muse, mutect2, varscan2
- THOC5 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV63799423; called by muse, mutect2, varscan2
- THSD7A | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.615); catalogued as COSV70267304; called by muse, mutect2, varscan2
- THUMPD3 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 110/330 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs770422877, COSV61506278; called by muse, mutect2
- TIFAB | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV72345852; called by muse, mutect2, varscan2
- TKTL2 | c.343del p.R115Dfs*12 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs542641888, COSV54917504; called by mutect2, pindel, varscan2
- TMC3 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs374926121; called by muse, mutect2, varscan2
- TMC5 | c.863dup p.E289Rfs*3 | Frame Shift Ins (INS) | VAF 32/140 reads (23%) | catalogued as rs770349191; called by mutect2, pindel, varscan2
- TMEM106A | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 97/325 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as rs1326785324, COSV57833534; called by muse, mutect2, varscan2
- TMEM119 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs752298653, COSV67188906; called by muse, mutect2
- TMIGD2 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.177); catalogued as COSV56667626; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs770800449; called by mutect2, varscan2
- TMPRSS12 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs374684282; called by muse, mutect2, varscan2
- TNFRSF13B | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1430117089, COSV55428688, COSV55430832; called by muse, mutect2, varscan2
- TOGARAM1 | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777475831, COSV61888603; called by muse, mutect2, varscan2
- TP53 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52750141, COSV52756133, COSV52784543, COSV52863408; called by muse, mutect2, varscan2
- TREM1 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55148895; called by muse, mutect2, varscan2
- TRIM7 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV51244872; called by muse, mutect2, varscan2
- TRIO | c.6719C>T p.S2240L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59990983; called by muse, mutect2, varscan2
- TRIO | c.8503G>A p.D2835N | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs768614002, COSV59990990, COSV59991796; called by muse, varscan2
- TRIP11 | c.2282A>G p.H761R | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV50932444; called by muse, mutect2, varscan2
- TRPV2 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV58429098; called by muse, mutect2, varscan2
- TSC22D4 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs763265650, COSV55724622; called by muse, mutect2, varscan2
- TSPAN11 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs768375131, COSV53819465; called by muse, mutect2, varscan2
- TTLL1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs747075337, COSV56738568, COSV56739339; called by muse, mutect2
- TTN | c.43033A>C p.S14345R (on ENST00000591111; = p.S6921R on NM_003319.4) | Missense Mutation (SNP) | VAF 48/163 reads (29%) | PolyPhen possibly damaging (0.656); catalogued as COSV60159891; called by muse, mutect2, varscan2
- TUBGCP6 | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs370132155; called by muse, mutect2, varscan2
- TUSC3 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as rs1252617740, COSV65881382; called by muse, mutect2, varscan2
- ULK1 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775402283, COSV58857959; called by muse, mutect2, varscan2
- UNC13C | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV52891845; called by muse, mutect2, varscan2
- USH2A | c.6523C>T p.R2175C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.877); catalogued as rs576163859, COSV100242695, COSV56389913; called by muse, mutect2, varscan2
- USP9Y | c.5491G>A p.V1831I | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV59099760; called by muse, mutect2, varscan2
- UTP20 | c.7031A>G p.K2344R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV55379845; called by muse, mutect2, varscan2
- UTRN | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs115273171; called by muse, mutect2, varscan2
- VANGL2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV63604324; called by muse, mutect2, varscan2
- VILL | c.1944G>A p.W648* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV52185729; called by muse, mutect2, varscan2
- VPS45 | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV64888233; called by muse, varscan2
- VSIR | c.856del p.L286Cfs*51 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs752718137, COSV56484595; called by mutect2, pindel, varscan2
- WARS2 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs747204006, COSV52479863; called by muse, mutect2, varscan2
- WDR7 | c.2991C>A p.D997E | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.967); catalogued as COSV54356734; called by muse, mutect2, varscan2
- WDTC1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs778371995, COSV60087726; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WSB2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs750000255, COSV57478034; called by muse, mutect2, varscan2
- WSCD1 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377198405; called by muse, mutect2, varscan2
- XIRP1 | c.3402del p.W1135Gfs*2 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | catalogued as rs1166941994; called by mutect2, pindel, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | catalogued as rs762052135; called by mutect2, varscan2
- ZBTB5 | c.1956G>C p.Q652H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV57040627; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs751577786; called by mutect2, varscan2
- ZC3H6 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59669000; called by muse, mutect2, varscan2
- ZCCHC2 | c.2157G>A p.M719I | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV54039279; called by muse, mutect2, varscan2
- ZFHX3 | c.9812C>T p.T3271M | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as rs759418149, COSV51723989; called by muse, mutect2, varscan2
- ZFHX4 | c.8981C>A p.P2994H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.479); catalogued as COSV51498864, COSV99255450; called by muse, mutect2, varscan2
- ZFPM1 | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as rs755947526, COSV60323315; called by muse, mutect2, varscan2
- ZMPSTE24 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV65639731; called by muse, mutect2
- ZNF185 | c.225G>A p.R75= | Splice Region (SNP) | VAF 12/53 reads (23%) | catalogued as rs782048278, COSV59276749; called by muse, mutect2, varscan2
- ZNF207 | c.1400T>C p.M467T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as rs1226016021, COSV58300731; called by muse, mutect2, varscan2
- ZNF217 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV56599002; called by muse, mutect2, varscan2
- ZNF248 | c.1505G>A p.C502Y | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.467); catalogued as COSV61998038; called by muse, mutect2, varscan2
- ZNF320 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as rs765248150, COSV67088412; called by muse, mutect2, varscan2
- ZNF322 | c.154T>G p.F52V | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV70652028; called by muse, mutect2, varscan2
- ZNF385A | c.900C>G p.H300Q (on ENST00000338010 / NM_001130967.3; = p.H280Q on NM_015481.3) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61493701; called by muse, mutect2, varscan2
- ZNF385A | c.714C>G p.I238M (on ENST00000338010 / NM_001130967.3; = p.I218M on NM_015481.3) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV61493742; called by muse, varscan2
- ZNF385A | c.613C>G p.L205V (on ENST00000338010 / NM_001130967.3; = p.L185V on NM_015481.3) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV61493755; called by muse, varscan2
- ZNF438 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as rs186136357, COSV59196778; called by muse, mutect2, varscan2
- ZNF497 | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1427493136, COSV54051903; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF536 | c.1378A>G p.M460V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62827438; called by muse, mutect2, varscan2
- ZNF566 | c.373A>G p.N125D | Missense Mutation (SNP) | VAF 9/287 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1211464108, COSV67574161; called by muse, mutect2
- ZNF589 | c.844G>T p.G282W | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61220641; called by muse, mutect2, varscan2
- ZNF618 | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV55924006; called by muse, mutect2, varscan2
- ZNF689 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as rs199718185, COSV54909058; called by muse, mutect2, varscan2
- ZNF780B | c.2407G>A p.V803I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55465571; called by muse, mutect2, varscan2
- ZNF816 | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV54411560; called by muse, mutect2, varscan2
- ZNF875 | c.1676G>A p.G559D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV60992402; called by muse, mutect2
- ABCB1 | c.1936del p.S646Vfs*17 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- ACSBG2 | c.230del p.K77Sfs*5 | Frame Shift Del (DEL) | VAF 55/255 reads (22%) | called by mutect2, pindel, varscan2
- ACVR2A | c.1148del p.L383* | Frame Shift Del (DEL) | VAF 85/310 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.312dup p.N105* | Frame Shift Ins (INS) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- AKAP13 | c.7511del p.K2504Rfs*50 (on ENST00000394518 / NM_007200.5; = p.K2508Rfs*50 on NM_006738.6) | Frame Shift Del (DEL) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- ANK2 | c.4212del p.F1404Lfs*28 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- ARHGAP30 | c.1418del p.P473Qfs*41 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- BTBD3 | c.290del p.P97Qfs*16 | Frame Shift Del (DEL) | VAF 21/195 reads (11%) | called by mutect2, pindel, varscan2
- CLDN19 | c.664del p.L222Wfs*66 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- CLYBL | c.1020dup p.*341Mfs*4 | Frame Shift Ins (INS) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.1779del p.K593Nfs*6 | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | called by mutect2, pindel, varscan2
- COL5A2 | c.4220del p.N1407Tfs*3 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- CYP4X1 | c.11_13del p.S4del | In Frame Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- DCP1B | c.984del p.F328Lfs*55 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- DDX50 | c.1017del p.K339Nfs*3 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- DNAH5 | c.13458del p.F4486Lfs*7 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- ERCC6L | c.1809_1813del p.L604Kfs*6 | Frame Shift Del (DEL) | VAF 15/25 reads (60%) | called by mutect2, pindel, varscan2
- FAM117A | c.1225dup p.L409Pfs*105 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- FAM135B | c.3898del p.T1300Qfs*46 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- FZD3 | c.959dup p.S321* | Frame Shift Ins (INS) | VAF 30/117 reads (26%) | called by mutect2, pindel, varscan2
- GALNT15 | c.409dup p.A137Gfs*2 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- GLT8D1 | c.433del p.E145Nfs*3 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- GPC4 | c.1032del p.K345Sfs*49 | Frame Shift Del (DEL) | VAF 65/166 reads (39%) | called by mutect2, varscan2
- GPR162 | c.1484del p.P495Hfs*60 (on ENST00000311268 / NM_019858.2; = p.P211Hfs*60 on NM_014449.2) | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | called by mutect2, pindel, varscan2
- HEPHL1 | c.93dup p.G32Wfs*79 | Frame Shift Ins (INS) | VAF 28/149 reads (19%) | called by mutect2, pindel, varscan2
- HYOU1 | c.2515dup p.A839Gfs*13 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- IGKV1-17 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 41/265 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- INSYN2A | c.371del p.K124Rfs*21 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- IQSEC1 | c.1326del p.R443Gfs*90 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- KLF5 | c.994del p.I332Lfs*59 | Frame Shift Del (DEL) | VAF 51/174 reads (29%) | called by mutect2, pindel, varscan2
- KLHL26 | c.1828del p.R610Gfs*32 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- LRP1 | c.4468del p.E1490Rfs*80 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | called by mutect2, pindel, varscan2
- MAP4K3 | c.781dup p.R261Kfs*5 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- MRPS18B | c.302_304del p.V101del | In Frame Del (DEL) | VAF 29/119 reads (24%) | called by pindel, varscan2
- MTG2 | c.279_280del p.H93Qfs*2 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by pindel, varscan2
- NCOA4 | c.392dup p.P132Afs*2 | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- NEK4 | c.2328_2335dup p.V779Gfs*3 | Nonsense Mutation (INS) | VAF 11/62 reads (18%) | called by mutect2, varscan2
- NLRC5 | c.5234_5237del p.I1745Tfs*27 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- NOMO1 | c.3620del p.P1207Qfs*84 | Frame Shift Del (DEL) | VAF 80/618 reads (13%) | called by mutect2, pindel, varscan2
- OR2D3 | c.763dup p.S255Ffs*34 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- OR5B21 | c.89del p.L30Yfs*14 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | called by mutect2, pindel, varscan2
- OVGP1 | c.1033dup p.R345Kfs*17 | Frame Shift Ins (INS) | VAF 34/151 reads (23%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PCGF3 | c.193del p.L65Cfs*26 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- PITPNM1 | c.884del p.P295Qfs*74 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- PLEC | c.9048del p.C3017Afs*43 (on ENST00000322810 / NM_201380.4; = p.C2907Afs*43 on NM_000445.5) | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- PLEKHM2 | c.16_18del p.V6del | In Frame Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- POLQ | c.4289del p.L1430* | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- POLR2B | c.1083del p.A362Pfs*21 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- PPP1R12C | c.1116del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- PSMD12 | c.1048del p.R350Gfs*5 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- PSPC1 | c.1541_1542del p.F514* | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- RAB42 | c.242del p.G81Vfs*119 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- RNF167 | c.72dup p.L25Afs*71 | Frame Shift Ins (INS) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- RRM2 | c.703_704del p.F235Lfs*24 | Frame Shift Del (DEL) | VAF 44/182 reads (24%) | called by mutect2, pindel, varscan2
- SAP130 | c.931_933del p.T311del | In Frame Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- SCAPER | c.1181del p.N394Mfs*12 | Frame Shift Del (DEL) | VAF 25/143 reads (17%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.252del p.F84Lfs*32 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- SMC6 | c.405_406del p.Y136Wfs*2 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by pindel, varscan2
- SNX29 | c.1936_1937del p.S646Ffs*5 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | called by pindel, varscan2
- SOBP | c.1388del p.P463Rfs*31 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- SOS1 | c.3090del p.K1030Nfs*6 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- SPAG17 | c.6222del p.F2074Lfs*25 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- ST8SIA1 | c.181del p.V61Cfs*34 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- STK38 | c.1146del p.F382Lfs*70 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- TJP1 | c.141dup p.Q48Sfs*19 | Frame Shift Ins (INS) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- TLE2 | c.744dup p.S249Qfs*30 | Frame Shift Ins (INS) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- TMC8 | c.1629dup p.L544Sfs*267 | Frame Shift Ins (INS) | VAF 31/131 reads (24%) | called by mutect2, pindel, varscan2
- TMPO | c.1220dup p.R409Tfs*36 | Frame Shift Ins (INS) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- TRPM7 | c.623dup p.V209Sfs*3 | Frame Shift Ins (INS) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.1803del p.M602Cfs*13 | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | called by mutect2, pindel, varscan2
- TTN | c.19338del p.F6446Lfs*7 (on ENST00000591111; = p.F5519Lfs*7 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- ULK1 | c.1967dup p.R657Sfs*44 | Frame Shift Ins (INS) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- USP38 | c.2469dup p.L824Ifs*7 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- VWA5A | c.1316del p.G439Afs*20 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 59/362 reads (16%) | called by mutect2, varscan2
- XIRP2 | c.3537dup p.E1180* (on ENST00000628543; = p.E1355* on NM_152381.6) | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- XKR4 | c.883dup p.M295Nfs*4 | Frame Shift Ins (INS) | VAF 32/132 reads (24%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.3018del p.K1006Nfs*31 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- ZC3H7A | c.2594del p.N865Tfs*47 | Frame Shift Del (DEL) | VAF 27/107 reads (25%) | called by mutect2, pindel, varscan2
- ZFR | c.1245del p.K415Nfs*42 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | called by mutect2, pindel
- ABCA9 | c.1524T>C p.Y508= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV60627159; called by muse, mutect2
- AC013489.1 | c.90C>T p.G30= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as COSV51552190; called by muse, mutect2, varscan2
- ACTR5 | c.1134G>A p.A378= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs745481440, COSV54760100; called by muse, mutect2, varscan2
- AGTPBP1 | c.3405A>G p.L1135= (on ENST00000357081 / NM_001330701.2; = p.L1095= on NM_015239.2) | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV61273568; called by muse, mutect2, varscan2
- AHCYL1 | c.837T>C p.N279= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV63208970; called by muse, mutect2
- AHRR | c.1128G>A p.E376= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57088685; called by muse, mutect2, varscan2
- ALK | c.2229C>T p.G743= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs111253753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANGPTL3 | c.894G>A p.T298= | Silent (SNP) | VAF 32/156 reads (21%) | catalogued as rs781130657, COSV52011688; called by muse, mutect2, varscan2
- ANKLE2 | c.2538C>T p.D846= | Silent (SNP) | VAF 69/219 reads (32%) | catalogued as rs764808473, COSV63294592; called by muse, mutect2, varscan2
- ANKRA2 | c.354T>C p.S118= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV57141318; called by muse, mutect2, varscan2
- AR | c.93C>T p.R31= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as COSV65952462; called by muse, mutect2, varscan2
- ATF2 | c.114C>T p.N38= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs748097470, COSV51370857; called by muse, mutect2, varscan2
- ATXN7L1 | c.306C>T p.C102= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs780160170, COSV59494215; called by muse, mutect2, varscan2
- C22orf42 | c.636C>T p.D212= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV66076261; called by muse, mutect2, varscan2
- CALR3 | c.759G>A p.A253= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1011639048, COSV54170528; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD22 | c.1380C>T p.G460= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs752070697, COSV50056908; called by muse, mutect2, varscan2
- CD59 | c.186C>T p.N62= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV60919524; called by muse, mutect2, varscan2
- CDC34 | c.447G>A p.R149= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV53117206; called by muse, mutect2, varscan2
- CDC42BPB | c.2643G>A p.S881= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs963766725, COSV63475668; called by muse, mutect2, varscan2
- CDKN2D | c.408C>T p.D136= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs554620640, COSV57263676; called by muse, mutect2, varscan2
- CEP170 | c.1149C>T p.N383= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs376260609; called by muse, mutect2
- CHRNG | c.1236G>A p.A412= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV67315704; called by muse, mutect2, varscan2
- CHST8 | c.693C>T p.S231= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs1442774348, COSV52860137; called by muse, mutect2, varscan2
- COL6A3 | c.5691G>A p.P1897= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs762064645, COSV55095671; called by muse, mutect2, varscan2
- COLGALT2 | c.1491C>T p.T497= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs267598230, COSV62299880, COSV62300102; called by muse, mutect2, varscan2
- CSF2RB | c.1470G>T p.G490= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV53258767; called by muse, mutect2, varscan2
- CTSB | c.876C>A p.P292= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV61540765; called by muse, mutect2, varscan2
- DAB2IP | c.2013G>A p.P671= (on ENST00000408936; = p.P643= on NM_032552.3) | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs371535507; called by muse, mutect2, varscan2
- DCN | c.612C>T p.Y204= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs771673142, COSV50007815; called by muse, mutect2, varscan2
- DIP2A | c.4701C>T p.V1567= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs190999418, COSV59480594; called by muse, mutect2, varscan2
- DNAH2 | c.5430C>T p.T1810= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs758278151, COSV66716128; called by muse, mutect2, varscan2
- DNAH5 | c.6270G>A p.R2090= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99444493; called by muse, mutect2
- DPP10 | c.750A>G p.R250= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV59697095; called by muse, mutect2, varscan2
- DRD5 | c.93G>A p.A31= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100431673, COSV58578952; called by muse, mutect2, varscan2
- EMC10 | c.538C>T p.L180= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1333563255, COSV58542582; called by muse, mutect2
- EPHA10 | c.2169C>T p.T723= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs748660646, COSV57625019; called by muse, mutect2, varscan2
- EPHA7 | c.1443C>T p.Y481= | Silent (SNP) | VAF 62/216 reads (29%) | catalogued as rs769720060, COSV65179978; called by muse, mutect2, varscan2
- ERN1 | c.666C>T p.Y222= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs757259673, COSV70503003; called by muse, mutect2, varscan2
- EVC | c.531C>T p.S177= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs542910336, COSV53834376; called by muse, mutect2, varscan2
- EVPL | c.5382T>C p.S1794= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV56912857; called by muse, mutect2, varscan2
- FAT4 | c.14421C>A p.I4807= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV58693301, COSV58696349, COSV99060133; called by muse, mutect2, varscan2
- FLNB | c.4782C>T p.Y1594= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs779187199, COSV55870823; called by muse, mutect2, varscan2
- FOXG1 | c.1299C>A p.S433= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV57397808; called by muse, mutect2, varscan2
- GBX2 | c.570C>T p.D190= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV60445414; called by muse, mutect2, varscan2
- GFI1B | c.192G>A p.P64= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs778912632, COSV59745541; called by muse, mutect2, varscan2
- GPS1 | c.1425G>A p.Q475= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs1024798705, COSV57649805; called by muse, mutect2, varscan2
- HOXC12 | c.168G>A p.P56= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs761620017, COSV54534695; called by mutect2, varscan2
- HOXD13 | c.537G>A p.P179= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV66832725, COSV66832881; called by muse, mutect2, varscan2
- HTR1A | c.90C>T p.D30= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV60499681; called by muse, mutect2, varscan2
- HYDIN | c.3216C>T p.Y1072= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1302603620, COSV66833099; called by muse, mutect2, varscan2
- IGHMBP2 | c.2574G>A p.Q858= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV54823632; called by muse, mutect2
- IGSF22 | c.1554C>T p.S518= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs371743611; called by muse, mutect2, varscan2
- IL2RB | c.1542C>A p.S514= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV53427096; called by muse, mutect2, varscan2
- INSR | c.2115G>A p.S705= | Silent (SNP) | VAF 7/147 reads (5%) | catalogued as rs1006491042, COSV57164476; called by muse, mutect2
- IQSEC3 | c.2847G>A p.S949= (on ENST00000538872 / NM_001170738.2; = p.S646= on NM_015232.1) | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs115184339, COSV100407155; called by muse, mutect2, varscan2
- IZUMO2 | c.165C>T p.A55= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs367559452; called by muse, mutect2, varscan2
- KCNH8 | c.783C>T p.D261= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV60468552; called by muse, mutect2, varscan2
- KCNK1 | c.534G>A p.V178= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV64035504; called by muse, mutect2, varscan2
- KCNK13 | c.1057C>T p.L353= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV56414394; called by muse, mutect2, varscan2
- KCNK9 | c.315G>A p.A105= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs760886822, COSV100271191, COSV57281092; called by muse, mutect2, varscan2
- KIF13B | c.3651T>C p.H1217= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV72954505; called by muse, mutect2, varscan2
- LAPTM5 | c.741G>A p.S247= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs1436527642, COSV53853730; called by muse, mutect2, varscan2
- LAYN | c.1044C>T p.S348= (on ENST00000375615 / NM_001258390.1; = p.S340= on NM_178834.5) | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as rs757102637, COSV65105035; called by muse, mutect2, varscan2
- LIMD1 | c.765C>T p.S255= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV56268448; called by muse, mutect2, varscan2
- LNPK | c.150C>T p.S50= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- LRP1 | c.3711C>T p.C1237= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs773532015, COSV54516580; called by muse, mutect2, varscan2
- LRRTM4 | c.213C>T p.N71= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV69140795; called by muse, mutect2, varscan2
- MAP3K2 | c.648T>C p.S216= | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as COSV61295028; called by muse, mutect2
- MAPT | c.2451C>T p.L817= (on ENST00000262410 / NM_001377265.1; = p.L425= on NM_005910.5) | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs200637464, COSV52242427; called by muse, mutect2, varscan2
- MEF2A | c.1069C>T p.L357= (on ENST00000557942 / NM_001319206.2; = p.L351= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57535083; called by muse, mutect2, varscan2
- MEIS2 | c.1323C>T p.H441= | Silent (SNP) | VAF 128/435 reads (29%) | catalogued as rs139991974, COSV54945949; called by muse, mutect2, varscan2
- MFAP2 | c.249A>G p.G83= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV65003877; called by muse, mutect2, varscan2
- MFSD2B | c.1386C>T p.G462= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs766151038, COSV57855221; called by muse, mutect2, varscan2
- MOCS1 | c.699G>A p.A233= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs1304693840, COSV57937468; called by muse, mutect2, varscan2
- MPHOSPH9 | c.792A>T p.V264= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV56621335; called by muse, mutect2, varscan2
- MRGPRX3 | c.210G>A p.A70= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs749919475, COSV66934205; called by muse, mutect2, varscan2
- MROH5 | c.672C>T p.Y224= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs764193147, COSV71302103; called by muse, mutect2, varscan2
- MROH7 | c.1182C>A p.I394= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV59874067; called by muse, mutect2, varscan2
- MRS2 | c.883C>T p.L295= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as COSV51234732; called by muse, mutect2, varscan2
- MTR | c.1707T>C p.P569= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs760490684, COSV63965491; called by muse, mutect2, varscan2
- MTURN | c.318G>A p.A106= | Silent (SNP) | VAF 77/255 reads (30%) | catalogued as rs753138328, COSV61023231; called by muse, mutect2, varscan2
- MYNN | c.972T>C p.H324= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as COSV62991618; called by muse, mutect2, varscan2
- MYT1 | c.1719G>A p.L573= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV60508509; called by muse, mutect2, varscan2
- NAAA | c.681G>A p.S227= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs766886886, COSV54432915; called by muse, mutect2, varscan2
- NLRP11 | c.2454C>T p.Y818= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as rs199475861; ClinVar: not provided; called by muse, mutect2, varscan2
- OBSL1 | c.960C>T p.A320= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV54723223; called by muse, mutect2, varscan2
- OR10AG1 | c.792G>A p.L264= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV56633555; called by muse, mutect2
- OR4D2 | c.309C>T p.F103= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV73459802; called by muse, mutect2, varscan2
- ORAI2 | c.462C>T p.T154= | Silent (SNP) | VAF 41/242 reads (17%) | catalogued as rs1239927039, COSV62689935; called by muse, mutect2, varscan2
- OTOP2 | c.1104C>T p.D368= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs768778471, COSV58882465; called by muse, mutect2, varscan2
- P2RY1 | c.609C>T p.Y203= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as rs1045138243, COSV59308851; called by muse, mutect2, varscan2
- PADI4 | c.129C>T p.N43= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs138052968; called by muse, mutect2, varscan2
- PCDH11X | c.2713C>T p.L905= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV100007824; called by muse, mutect2
- PCDH11X | c.3529C>T p.L1177= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV53479602; called by muse, mutect2, varscan2
- PCDH9 | c.894A>G p.A298= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as rs879368261, COSV60564284; called by muse, mutect2, varscan2
- PCDHB4 | c.1587C>T p.R529= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV99521817; called by muse, varscan2
- PCYT1B | c.375C>T p.T125= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as rs757374830, COSV63265546; called by muse, mutect2, varscan2
- PDE6A | c.1659C>T p.Y553= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV54928911, COSV99678363; called by muse, varscan2
- PIK3AP1 | c.1545G>A p.T515= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs375373941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKDREJ | c.2064G>T p.V688= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV53550368; called by muse, mutect2, varscan2
- PLAG1 | c.171A>G p.T57= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57609073; called by muse, mutect2, varscan2
- PLPP2 | c.690G>A p.L230= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99514430; called by mutect2, varscan2
- PMPCB | c.780C>T p.F260= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs753165205, COSV50786629; called by muse, mutect2, varscan2
- PPFIA4 | c.1818G>A p.T606= (on ENST00000447715; = p.T607= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs777906811, COSV55317376; called by muse, mutect2, varscan2
- PPIL2 | c.363G>A p.T121= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs746372969, COSV58607207; called by muse, mutect2, varscan2
- PRRC2B | c.909T>C p.F303= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs750519618, COSV61939142; called by muse, mutect2, varscan2
- PSG2 | c.522G>A p.P174= | Silent (SNP) | VAF 91/282 reads (32%) | catalogued as rs146429644, COSV61546335; called by muse, mutect2, varscan2
- PTPRA | c.1050C>T p.C350= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs778195981, COSV53781127; called by muse, mutect2, varscan2
- RHBDL3 | c.381G>A p.K127= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV52187290; called by muse, mutect2, varscan2
- RPS24 | c.105G>A p.V35= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV62602675; called by muse, mutect2, varscan2
- RXFP3 | c.198G>A p.P66= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs760906672, COSV57506584; called by muse, mutect2, varscan2
- SCRT1 | c.681C>T p.C227= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1554849891, COSV59781678; called by muse, mutect2, varscan2
- SEMA6B | c.261C>T p.R87= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs774865159, COSV56704581; called by muse, mutect2, varscan2
- SHTN1 | c.342T>C p.T114= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV53384189; called by muse, mutect2, varscan2
- SIGLEC12 | c.1752C>T p.I584= (on ENST00000291707 / NM_053003.4; = p.I466= on NM_033329.2) | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs532504299, COSV52462721; called by muse, mutect2, varscan2
- SIX1 | c.432G>A p.A144= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs1384441868, COSV55960368; called by muse, mutect2, varscan2
- SLC10A2 | c.708G>A p.A236= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as rs1041398293, COSV55360173; called by muse, mutect2, varscan2
- SLC17A7 | c.1326C>T p.N442= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs971797832, COSV55548445; called by muse, mutect2, varscan2
- SLC5A6 | c.1884C>T p.C628= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV60160171; called by muse, mutect2, varscan2
- SLCO1B1 | c.210C>T p.D70= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs148697674; called by muse, mutect2
- SLITRK3 | c.2253C>T p.C751= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV53849878; called by muse, mutect2, varscan2
- SNX14 | c.255A>G p.K85= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV59013801; called by muse, mutect2, varscan2
- SPTBN1 | c.3072C>T p.S1024= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV61690164; called by muse, mutect2, varscan2
- STAU1 | c.618G>T p.R206= (on ENST00000371856 / NM_001319135.1; = p.R125= on NM_004602.3) | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV61460914; called by muse, mutect2, varscan2
- TAL1 | c.60C>T p.D20= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53747458; called by muse, mutect2, varscan2
- TAPBP | c.243G>C p.R81= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV69667892; called by muse, mutect2
- TBX19 | c.495T>C p.Y165= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV63197830; called by muse, mutect2
- TCERG1 | c.2305C>A p.R769= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV57038768; called by muse, mutect2
- TG | c.1116G>A p.L372= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as COSV55070432; called by muse, mutect2, varscan2
- TGFB2 | c.195G>A p.P65= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV65109948; called by muse, mutect2, varscan2
- TIGAR | c.360C>T p.P120= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs770821333, COSV51628598; called by muse, mutect2, varscan2
- TIRAP | c.433C>T p.L145= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV67024340; called by mutect2, varscan2
- TLE4 | c.1134C>A p.P378= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as COSV54634916; called by muse, mutect2, varscan2
- TNXB | c.6498C>T p.D2166= (on ENST00000647633; = p.D1919= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/181 reads (32%) | catalogued as rs371329474; called by muse, mutect2, varscan2
- TPD52L2 | c.69G>A p.T23= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs929634458, COSV53863155; called by muse, mutect2, varscan2
- TSHZ1 | c.2919C>T p.N973= (on ENST00000580243 / NM_001308210.2; = p.N928= on NM_005786.6) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs771320123, COSV59012368; called by muse, mutect2, varscan2
- TTC7A | c.1719A>G p.A573= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs1378405271, COSV55412602; called by muse, mutect2, varscan2
- TTN | c.66444C>T p.T22148= (on ENST00000591111; = p.T14724= on NM_003319.4) | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV60159850; called by muse, mutect2, varscan2
- TUBB4A | c.321G>A p.T107= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs759144466, COSV51156136, COSV51158039; called by muse, mutect2, varscan2
- UGT1A1 | c.177C>T p.V59= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV59392103; called by muse, mutect2, varscan2
- USH2A | c.8316T>G p.T2772= | Silent (SNP) | VAF 63/205 reads (31%) | catalogued as COSV56392099; called by muse, mutect2, varscan2
- USP3 | c.1425C>T p.Y475= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs746051369, COSV51428277; called by muse, mutect2, varscan2
- USP34 | c.1581C>T p.S527= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs369590862; called by muse, mutect2, varscan2
- VCAN | c.6711G>A p.P2237= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs747734140, COSV54108886; called by muse, mutect2, varscan2
- VCL | c.2604T>C p.G868= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV53011293; called by muse, mutect2, varscan2
- VWA8 | c.4695C>T p.G1565= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs774671827, COSV64993848; called by muse, mutect2, varscan2
- ZBTB6 | c.414A>G p.Q138= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV65409806; called by muse, mutect2
- ZNF385A | c.822C>G p.V274= (on ENST00000338010 / NM_001130967.3; = p.V254= on NM_015481.3) | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV61493717, COSV61494029; called by muse, varscan2
- ZNF423 | c.2763G>A p.P921= (on ENST00000563137 / NM_001379286.1; = p.P913= on NM_015069.4) | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs571689478, COSV52190599; called by muse, mutect2, varscan2
- ZNF484 | c.1359A>G p.S453= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV60258351; called by muse, mutect2, varscan2
- COL25A1 | c.-2C>T | 5'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as rs758629198, COSV67652641; called by muse, mutect2, varscan2
- EIF4A2 | c.208+130C>T | Intron (SNP) | VAF 35/109 reads (32%) | catalogued as rs747506625, COSV100125299; called by muse, mutect2, varscan2
- FAIM | c.1del | 5'UTR (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- KDM4B | c.1115+636G>A | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99345422; called by muse, mutect2
- MIR124-2 | n.37G>A | RNA (SNP) | VAF 15/38 reads (39%) | catalogued as rs1261326747; called by muse, mutect2, varscan2
- PDE4B | c.635-21T>C | Intron (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100302071; called by muse, mutect2, varscan2
- RNF213 | c.3024+103G>A | Intron (SNP) | VAF 29/102 reads (28%) | catalogued as rs541581943, COSV100172970; called by muse, mutect2, varscan2
- RPS2 | c.375+49_375+50del | Intron (DEL) | VAF 8/28 reads (29%) | catalogued as rs199524533; called by pindel, varscan2
- SNORD116-19 | n.69G>T | RNA (SNP) | VAF 58/154 reads (38%) | called by muse, mutect2, varscan2
- SSPOP | n.8477C>T | RNA (SNP) | VAF 5/11 reads (45%) | catalogued as rs1310240931, COSV65132382; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+464G>T | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as rs778979723, COSV101530509; called by muse, mutect2
- TTLL12 | c.*806G>A | 3'UTR (SNP) | VAF 12/45 reads (27%) | catalogued as rs772911324, COSV99333126; called by muse, mutect2, varscan2
- ZSCAN32 | c.915-87T>C | Intron (SNP) | VAF 4/96 reads (4%) | catalogued as COSV100514155; called by muse, mutect2
